Somatic mutation profile of tumor specimen 0DX7FT from CCDI case PBCPZG, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Spinal cord; Age at diagnosis: 3.9 years (1,425 days).
Specimen 0DX7FT: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a96b7283-6d74-4c3d-b357-2de979a656cd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DX7EV (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2cd16eab-90d5-468e-b9a2-5b47bb9b6e91

The open-access MAF lists 37 somatic variants for this specimen: 26 protein-altering or splice-affecting, 6 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 25, Silent 6, Intron 3, Splice Site 1, 5'Flank 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS9 | c.725G>A p.R242K | Missense Mutation (SNP) | VAF 238/349 reads (68%) | SIFT tolerated (0.95); PolyPhen benign (0); catalogued as COSV55789955; called by muse, varscan2
- CNBD2 | c.1068G>T p.W356C | Missense Mutation (SNP) | VAF 289/667 reads (43%) | SIFT tolerated (0.17); PolyPhen benign (0.339); catalogued as COSV62587802; called by muse, mutect2, varscan2
- DNAH9 | c.12897C>A p.F4299L | Missense Mutation (SNP) | VAF 188/534 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52363866; called by muse, mutect2, varscan2
- MUC17 | c.2245T>A p.L749I | Missense Mutation (SNP) | VAF 126/607 reads (21%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV60302745; called by muse, mutect2, varscan2
- NOTUM | c.856G>A p.A286T | Missense Mutation (SNP) | VAF 122/600 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.255); catalogued as rs370368298, COSV68826262; called by muse, varscan2
- PKHD1 | c.9364G>A p.V3122M | Missense Mutation (SNP) | VAF 55/1097 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1282660796; called by muse, mutect2
- POLRMT | c.1056C>G p.H352Q | Missense Mutation (SNP) | VAF 67/184 reads (36%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as rs372017487; called by muse, varscan2
- SUCLA2 | c.1282C>T p.R428W (on ENST00000643023; = p.R407W on NM_003850.3) | Missense Mutation (SNP) | VAF 250/712 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1233249991, CM162763, COSV66222631; called by muse, mutect2, varscan2
- ZFHX4 | c.7699C>A p.H2567N | Missense Mutation (SNP) | VAF 188/566 reads (33%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.783); catalogued as COSV51502970, COSV99268479; called by muse, mutect2, varscan2
- ABCA12 | c.3862C>G p.P1288A (on ENST00000272895 / NM_173076.3; = p.P970A on NM_015657.3) | Missense Mutation (SNP) | VAF 29/1086 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.624); called by muse, mutect2
- ADAMTS3 | c.2237A>G p.D746G | Missense Mutation (SNP) | VAF 325/1063 reads (31%) | SIFT tolerated (0.34); PolyPhen benign (0.207); called by muse, varscan2
- CFAP44 | c.1684G>A p.D562N | Missense Mutation (SNP) | VAF 380/957 reads (40%) | SIFT tolerated (0.42); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CLDN23 | c.814C>A p.Q272K | Missense Mutation (SNP) | VAF 107/269 reads (40%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CRACDL | c.1939C>A p.P647T | Missense Mutation (SNP) | VAF 107/246 reads (43%) | SIFT tolerated (0.77); PolyPhen benign (0); called by muse, mutect2, varscan2
- DOCK10 | c.4268+2T>C p.X1423_splice | Splice Site (SNP) | VAF 70/962 reads (7%) | called by muse, mutect2
- DPYD | c.119A>T p.H40L | Missense Mutation (SNP) | VAF 532/1483 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- GDAP1 | c.488A>G p.Q163R | Missense Mutation (SNP) | VAF 169/544 reads (31%) | SIFT tolerated (0.19); PolyPhen benign (0.053); called by muse, varscan2
- MYO3B | c.1405C>A p.L469I | Missense Mutation (SNP) | VAF 65/1038 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2
- PCDH18 | c.2937G>T p.K979N | Missense Mutation (SNP) | VAF 39/1278 reads (3%) | SIFT tolerated (0.48); PolyPhen benign (0.343); called by muse, mutect2
- PTPRCAP | c.104C>A p.T35N | Missense Mutation (SNP) | VAF 64/174 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- SLC6A16 | c.1351C>A p.Q451K | Missense Mutation (SNP) | VAF 33/697 reads (5%) | SIFT tolerated (0.66); PolyPhen benign (0.033); called by muse, mutect2
- SPHKAP | c.472C>A p.Q158K | Missense Mutation (SNP) | VAF 54/1111 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); called by muse, mutect2
- TNFSF18 | c.535C>A p.Q179K | Missense Mutation (SNP) | VAF 41/1376 reads (3%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.727); called by muse, mutect2
- UBC | c.1901T>A p.V634D | Missense Mutation (SNP) | VAF 127/499 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- XPO7 | c.2077C>T p.P693S | Missense Mutation (SNP) | VAF 28/714 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.882); called by muse, mutect2
- YIPF4 | c.377C>A p.S126Y | Missense Mutation (SNP) | VAF 385/755 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- CARMIL1 | c.1248C>T p.F416= | Silent (SNP) | VAF 76/1296 reads (6%) | called by muse, mutect2
- FPR1 | c.717C>A p.P239= | Silent (SNP) | VAF 121/383 reads (32%) | called by muse, mutect2, varscan2
- GLT8D2 | c.162G>T p.V54= | Silent (SNP) | VAF 28/716 reads (4%) | called by muse, mutect2
- PIK3C2B | c.3972G>T p.L1324= | Silent (SNP) | VAF 30/550 reads (5%) | called by muse, mutect2
- SCARF1 | c.1707C>T p.D569= | Silent (SNP) | VAF 24/360 reads (7%) | catalogued as rs1215900468; called by muse, mutect2
- TOGARAM2 | c.2859G>A p.V953= | Silent (SNP) | VAF 17/521 reads (3%) | catalogued as rs1386009825; called by muse, mutect2
- CD48 | c.652+164C>A | Intron (SNP) | VAF 65/266 reads (24%) | called by muse, mutect2, varscan2
- CDC23 | c.1504-32G>C | Intron (SNP) | VAF 146/383 reads (38%) | called by muse, mutect2, varscan2
- OR8A1 | c.*91A>C | 3'UTR (SNP) | VAF 4/76 reads (5%) | called by muse, mutect2
- PTPRB | c.5124+53C>T | Intron (SNP) | VAF 151/354 reads (43%) | catalogued as rs938473169; called by muse, mutect2, varscan2
- STRIT1 | chr3:155293705 T>C | 5'Flank (SNP) | VAF 32/1123 reads (3%) | called by muse, mutect2
